Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5259, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5259-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: Liver C22.0 1/28/11 hr

ID#:

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	12 x 8 x 6 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 4 N0 M0 Stage: IV			
Notes:			

Discrepancy/Secondary Primary Noted		X

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern																								
Cell Distribution			+	-	Structural Pattern			+	-															
Diffuse			✓		Streaming																			
Mosaic					Storiform																			
Necrosis			✓		Fibrosis																			
Lymphocytic Infiltration					Palisading																			
Vascular Invasion					Cystic Degeneration																			
Clusterized					Bleeding																			
Alveolar Formation					Myxoid Change																			
Indian File					Psammoma/Calcification																			
Cellular Differentiation																								
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-					
Squamoid Cell					Glandular cell			✓		Round Cell					Large Cell									
Spindle Cell					Cell Stratification					Fibroblast					Small Cell									
Keratin					Secretion					Osteoblast					RS Cell/RS Like									
Desmosome					Intracyt. Vacuole					Lipoblast					Inflam. Cell									
Pearl					Gland formation					Myoblast					Plasma Cell									
Cellular Differentiation:					Well					Moderate					Poor									
Nuclear Appearance																								
Nuclear Atypia:					0					I					II					III				
Aniso Nucleosis										✓														
Hyperchromatism															✓									
Nucleolar Prominent															✓									
Multinucleated Giant Cell															✓									
Mitotic Activity															✓									
Nuclear Grade:																								

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Hepatocarcinoma
Moderately differentiated Grade: III

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis	☒		Fibrosis		
Lymphocytic Infiltration	☒		Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psamomma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		

Otherwise Specified: D, 50% D2 50% D3 50% D4 50% Necrosis > 30%

2. Cellular Differentiation:

Well	Modexately	Poor
	☒	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade			2	

Histological Diagnosis: hepato cellular carcinoma, G 2

Comments: _____

Date _____

Source: NCI Genomic Data Commons file 47e3ef71-af02-45a8-bcea-5fc5c388175e (TCGA-CC-5259.BE330AF3-7D80-4588-80D1-2C24F0158BFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).